Surgical pathology report (de-identified scan), TCGA case TCGA-14-1458, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1458-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

* Final Report *

TCGA-14-1458

AP REPORT

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT PARIETAL LESION, BIOPSY, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. LEFT PARIETAL LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).
- SEE COMMENT.

COMMENT:

The majority of the tumor shows features of grade II-III glioma with microcystic change and calcification. The majority of the tumor is astrocytic while oligodendroglial component is seen in areas. Cellularity is moderate in most but dense in other areas. Several areas of necrosis are seen. Vascular proliferation is not seen.

SPECIMEN:

1. Left parietal lesion.
2. Left parietal lesion.

Printed by:
Printed on:

[page 2 of 2]
AP Report

* Final Report *

CLINICAL HISTORY/OPERATIVE FINDINGS:

Brain tumor.

GROSS DESCRIPTION:

Two specimens are received, labeled with the patient's name and medical record number. Specimen #1 is received fresh for intraoperative consultation, and specimen #2 is received in formalin.

Specimen #1 is labeled "left parietal brain lesion." The specimen consists of multiple fragments of white tissue, measuring 2.3 x 1.5 x 0.2 cm. Representative tissue is submitted for frozen section diagnosis. A touch preparation is made. Contents of the cryoblock are transferred to cassette "FS1A." The remainder of the specimen is submitted in cassette "1B."

Specimen #2 is labeled "left parietal brain lesion." The specimen consists of multiple fragments of red tissue, measuring 4.8 x 4.0 x 2.0 cm. Representative sections are submitted in cassettes "2A" through "2D."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT PARIETAL LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION):
INFILTRATING GLIOMA.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 7aea592b-0e66-45af-87f3-3d89ec0c5544 (TCGA-14-1458.B3D7230A-7D53-4967-8A46-749A593D6711.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).